Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48N, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48N-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

....

Clinical Diagnosis & History:

Retroperitoneal dedifferentiated liposarcoma en block resection.

Specimens Submitted:

- 1: Left retroperitoneal liposarcoma with sigmoid colon
- 2: Deep iliac vein
- 3: Distal margin
- 4: Proximal margin

DIAGNOSIS:

1. Retroperitoneum, left, with portion of sigmoid colon, tumor, resection:
- Dedifferentiated liposarcoma arising in a background of well-differentiated liposarcoma. (see Note)
- The tumor measures 13.0 cm in greatest dimension.
- The dedifferentiated component constitutes more than 95% and is a low grade spindle cell sarcoma.
- Well-differentiated liposarcoma, lipoma-like.
- The tumor is covered with a thin fibrous membrane.
- Segment of colon with no significant pathologic changes.

Note: Prior biopsy as reviewed.

2. Soft tissue, deep iliac vein, resection:
- Well-differentiated liposarcoma, sclerosing-type.
- Four benign lymph nodes (0/4).
3. Colon, distal margin, excision:
- Benign segment of colon.
4. Colon, proximal margin, excision:
- Benign segment of colon.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

ICD-O-3

liposarcoma, dedifferentiated

885813

Site: retroperitoneum

9/11/12

C48.0

RD

[page 2 of 3]
SURGICAL [REDACTED]

----- Page 2 of 3

Gross Description:

1). The specimen is received fresh, labeled "left retroperitoneal liposarcoma with sigmoid colon". It contains a segment of sigmoid colon with attached tan-yellow mass. The sigmoid colon measures 24.5 cm in length and 2.5 cm in average circumference. A tan-white to tan-yellow mass is identified at the serosa surface of the sigmoid colon, measures 13 x 9.5 x 8 cm. Cut surface is tan-yellow, slightly gelatinous, there are tan-white firm areas identified. The mass is covered by a thin membrane. Upon opening of the sigmoid colon, the mucosa is unremarkable. The membrane of the mass is inked black. Photographs are taken. TBS is taken. The specimen is representatively submitted.

Summary sections:

S-sigmoid colon, representative

M.-mass, representative

F-firm area, representative

ADD-additional sections adjacent to the mass

2). The specimen is received in formalin labeled, "The iliac vein" and consists of pink-tan fibrofatty cauterized tissues measuring 2.3 x 1.5 x 0.8 cm. Submitted in total.

Summary of section:

U-undesignated

3). The specimen is received in formalin, labeled "Distal margin" and consists of a ring of pink tan soft tissue measuring 2.5 x 2.3x 1.1 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

4). The specimen is received in formalin, labeled "Proximal margin" and consists of a ring of pink tan soft tissue measuring 3.5 x 2.3x 1.1 cm. The mucosal surface is pink tan and focally hemorrhagic. The soft tissue is entirely submitted.

Summary of sections:

U - undesignated

** Continued on next page **

[page 3 of 3]
SURGICAL

Page 3 of 3

Summary of Sections:

Part 1: Left retroperitoneal liposarcoma with sigmoid colon

Block	Sect.	Site	PCs
4		ADD	4
8		F	16
8		M	16
1		S	2

Part 2: Deep iliac vein

Block	Sect.	Site	PCs
3		u	10

Part 3: Distal margin

Block	Sect.	Site	PCs
3		u	10

Part 4: Proximal margin

Block	Sect.	Site	PCs
3		u	10

** End of Report **

Source: NCI Genomic Data Commons file 33e6a561-511e-49f2-b22c-784777f79f41 (TCGA-DX-A48N.80BF27B0-6CB2-4D79-8147-25DB218565C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).